FM case AD1406 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/366c18ba-7bf4-4f25-8729-b5edef626827

Male, 69.2 years: Carcinoma, NOS (ICD-O-3 8010/3); specimen biopsied or resected from the peritoneum. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Tumor.
